Gene-level copy-number profile of tumor specimen TCGA-P6-A5OH-01A from TCGA case TCGA-P6-A5OH, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 59.2 years (21,627 days).
Specimen TCGA-P6-A5OH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.3c8a901a-645d-401d-938b-abc7d6e2ad2a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-P6-A5OH-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/af47f33a-f0dd-4058-8892-5ec9e3627982

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 616; copy number 2: 5,066; copy number 3: 4,759; copy number 4: 28,934; copy number 5: 8,749; copy number 6: 10,303; copy number 7: 448; copy number 8: 902; copy number 10: 33.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-P6-A5OH-01A-11D-A309-01): tumor purity 0.8, ploidy 3.17, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 33 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:120,438,090–120,980,965, 33 genes, copy number 10: COX6A1, AL021546.1, TRIAP1, GATC, RPL31P52, SRSF9, DYNLL1, NRAV, AC063943.1, COQ5, Y_RNA, RPL29P24, RNF10, AC063943.2, POP5, RPL11P5, AC125616.1, CABP1, MLEC, AC069234.2, AC069234.5, AC069234.4, UNC119B, AC069234.3, MIR4700, ACADS, AC069234.1, SPPL3, ARF1P2, AC069214.1, CLIC1P1, RPL12P33, HNF1A-AS1.

Autosomal genes at a single copy (total copy number 1): 616. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
